Gene-level copy-number profile of tumor specimen TCGA-RD-A7C1-01A from TCGA case TCGA-RD-A7C1, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 82.6 years (30,171 days).
Specimen TCGA-RD-A7C1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.a024c871-81f5-4cd9-83d8-c959633d3f9a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RD-A7C1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/81631f6e-1041-4b32-92a0-5cca83e4218d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 394; copy number 2: 2,466; copy number 3: 28,066; copy number 4: 19,164; copy number 5: 3,569; copy number 6: 3,814; copy number 7: 628; copy number 8: 812; copy number 9: 210; copy number 10: 129; copy number 11: 37; copy number 12: 173; copy number 13: 152; copy number 14: 2; copy number 15: 22; copy number 17: 33; copy number 21: 38; copy number 25: 5; copy number 28: 34; copy number 29: 25; copy number 34: 11; copy number 36: 6; copy number 83: 7; copy number 84: 7; copy number 96: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RD-A7C1-01A-11D-A32M-01): tumor purity 0.31, ploidy 3.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,341 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:100,208,254–103,019,900, 56 genes, copy number 8 (within-gene range 6–8): LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3, NPAS2, AC092168.2, NPAS2-AS1, AC016738.1, RPL31, TBC1D8, BBIP1P1, TBC1D8-AS1, CNOT11, RNF149, SNORD89, MIR5696, CREG2, AC092570.1, RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796.
- chr2:187,712,816–188,384,313, 1 gene, copy number 7 (within-gene range 3–7): LINC01090.
- chr2:188,227,189–204,307,364, 283 genes, copy number 7–10 (broad region; genes not listed).
- chr2:207,166,120–208,358,746, 40 genes, copy number 7–11: MYOSLID, MIR7845, AC007879.1, AC007879.3, AC007879.5, AC007879.2, AC007879.4, AC009226.1, LINC01802, MIR1302-4, CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2, IDH1, IDH1-AS1, PIKFYVE, MYL6BP1.
- chr2:208,360,631–208,540,413, 4 genes, copy number 11: ARPC1BP1, H3P9, AC019185.1, AC019185.2.
- chr3:115,802,363–117,139,389, 6 genes, copy number 7 (within-gene range 4–7): LSAMP, RN7SL815P, LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2.
- chr6:92,002,610–92,180,156, 1 gene, copy number 15 (within-gene range 3–15): AL590814.1.
- chr6:92,119,423–92,888,581, 6 genes, copy number 15: U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1.
- chr6:101,181,257–107,459,564, 59 genes, copy number 8–17 (within-gene range 4–17): GRIK2, ACTG1P18, AP002528.1, AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr6:107,509,803–107,511,721, 1 gene, copy number 17: AL121957.1.
- chr6:118,460,772–118,710,075, 1 gene, copy number 13 (within-gene range 4–13): CEP85L.
- chr6:118,548,296–119,391,829, 15 genes, copy number 13: PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2, MAN1A1, AL022722.1, RNU6-194P, AL078600.1.
- chr7:54,752,250–57,837,046, 146 genes, copy number 13–96 (broad region; genes not listed).
- chr11:31,432,401–32,104,665, 6 genes, copy number 36 (within-gene range 2–36): IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4.
- chr11:32,387,775–36,232,136, 83 genes, copy number 11–34 (broad region; genes not listed).
- chr11:44,726,465–46,386,608, 43 genes, copy number 10–84 (within-gene range 2–84): TSPAN18, TP53I11, LINC02685, AC068858.1, PRDM11, AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4.
- chr11:46,428,653–46,451,889, 3 genes, copy number 83: AC024293.1, MIR3160-1, MIR3160-2.
- chr11:48,880,111–50,422,316, 57 genes, copy number 8: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, AC084851.4, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1, TYRL, CBX3P8, AC135977.1, AC136759.1, AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C48P, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, AC109635.5, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr11:66,520,637–85,627,922, 491 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr11:87,648,489–94,621,421, 166 genes, copy number 7–10 (broad region; genes not listed).
- chr11:94,559,018–94,640,833, 2 genes, copy number 10 (within-gene range 6–10): AP000943.3, AP000943.1.
- chr18:20,946,906–23,586,506, 59 genes, copy number 12–29: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA.
- chr20:33,031,648–64,313,132, 812 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
